Gene-level copy-number profile of tumor specimen TCGA-CV-7434-01A from TCGA case TCGA-CV-7434, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 64.2 years (23,465 days).
Specimen TCGA-CV-7434-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.d3126a73-f842-4c85-905c-fd2df9af3e3e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7434-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/517ecddf-dc58-4aed-afe6-78c7fb2c0476

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 7,250; copy number 2: 41,578; copy number 3: 6,258; copy number 4: 3,832; copy number 5: 434; copy number 6: 67; copy number 7: 31; copy number 8: 299; copy number 10: 8; copy number 11: 5; copy number 14: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7434-01A-11D-2128-01): tumor purity 0.71, ploidy 2.25, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–746,106, 19 genes (within-gene range 0–8): WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1.
- chr9:21,638,285–22,029,594, 11 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes: AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr18:80,109,262–80,247,514, 5 genes (within-gene range 0–14): ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 851 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:39,436,530–40,255,209, 5 genes, copy number 5 (within-gene range 3–5): MAP4K3-DT, TMEM178A, THUMPD2, SLC8A1-AS1, AC007253.1.
- chr3:189,631,389–193,593,111, 45 genes, copy number 5: TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC, OSTN, OSTN-AS1, UTS2B, CCDC50, AC073365.1, PYDC2, Y_RNA, AC026320.2, AC026320.1, AC026320.3, RN7SKP222, FGF12, FGF12-AS1, FGF12-AS2, FGF12-AS3, AC026671.1, RNU1-20P, MB21D2, AC092966.1, VEZF1P1, PLAAT1, ATP13A5, ATP13A5-AS1, ATP13A4, ATP13A4-AS1, AC048351.1.
- chr6:98,179,499–100,881,372, 30 genes, copy number 5 (within-gene range 4–5): EIF4EBP2P3, AL590727.1, AL589826.1, AL589826.2, POU3F2, FBXL4, AL078603.1, MIR548AI, BDH2P1, FAXC, COQ3, PNISR, AL513550.1, USP45, TSTD3, Y_RNA, CCNC, AL137784.1, PRDM13, Y_RNA, MCHR2, MCHR2-AS1, NPM1P38, AL080285.2, PRDX2P4, AL080285.1, SIM1, SIM1-AS1, ASCC3, Z86062.1.
- chr9:841,690–21,559,900, 286 genes, copy number 8 (broad region; genes not listed).
- chr9:21,994,139–22,128,103, 1 gene, copy number 8 (within-gene range 0–8): CDKN2B-AS1.
- chr9:22,117,665–27,066,134, 38 genes, copy number 6–11: AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19.
- chr9:37,512,547–38,069,227, 15 genes, copy number 5–10 (within-gene range 1–10): AL513165.2, TOMM5, AL138752.2, RAB1C, FRMPD1, RN7SKP171, TRMT10B, EXOSC3, DCAF10, AL138752.1, PAICSP1, SLC25A51, TMX2P1, SHB, RNU7-124P.
- chr18:47,390–21,704,780, 391 genes, copy number 5–6 (broad region; genes not listed).
- chr18:21,711,950–21,724,229, 2 genes, copy number 5: AC106037.1, Y_RNA.
- chr18:22,418,829–23,026,488, 11 genes, copy number 5: ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.
- chr18:79,959,579–80,097,088, 7 genes, copy number 14: AC114341.2, HSBP1L1, TXNL4A, AC090360.1, RBFA, RBFADN, SLC25A6P4.
- chr22:49,718,053–50,085,426, 20 genes, copy number 7 (within-gene range 1–7): AL023802.1, RN7SKP252, RPL5P35, BRD1, Z98885.3, Z98885.1, Z98885.2, AL117328.1, Metazoa_SRP, AL117328.2, ZBED4, ALG12, AL671710.1, CRELD2, BX539320.1, PIM3, MIR6821, IL17REL, TTLL8, MLC1.

Autosomal genes at a single copy (total copy number 1): 4,829. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
